Somatic mutation profile of tumor specimen TCGA-HW-7495-01A (aliquot TCGA-HW-7495-01A-11D-2024-08) from TCGA case TCGA-HW-7495, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 45.1 years (16,460 days).
Specimen TCGA-HW-7495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98ecc247-fdea-4e66-bc07-bcf4b0c8979f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-7495-10A (Blood Derived Normal), aliquot TCGA-HW-7495-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d59a00d-83b5-4b36-adee-affd0c1b8c54

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BAX | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as COSV53169046; called by muse, mutect2, varscan2
- BOC | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929050045, COSV99847773, COSV99848077; called by muse, mutect2
- CADPS2 | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV57349478; called by muse, mutect2
- CELSR2 | c.4670A>G p.D1557G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54766762; called by muse, mutect2
- CTNNA2 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58134821; called by muse, mutect2, varscan2
- DOCK8 | c.333-1G>A p.X111_splice | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV66632909, COSV66636317; called by muse, mutect2, varscan2
- SH3KBP1 | c.278A>T p.N93I | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV65639149; called by muse, mutect2, varscan2
- WDR44 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV54160134, COSV54170626; called by muse, mutect2, varscan2
- ZNF579 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1263860770, COSV57637192; called by muse, mutect2
- CIC | c.4246del p.R1416Dfs*38 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- CRLF3 | c.1026A>G p.G342= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as COSV60835199; called by muse, varscan2
- DNAH11 | c.2898G>A p.G966= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV60939865; called by muse, mutect2
- PRDM10 | c.465G>A p.T155= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs1375152056, COSV58799289; called by muse, mutect2, varscan2
- RREB1 | c.3809-5951T>A | Intron (SNP) | VAF 36/138 reads (26%) | catalogued as COSV58553413; called by muse, mutect2, varscan2
